Somatic mutation profile of tumor specimen TCGA-17-Z052-01A (aliquot TCGA-17-Z052-01A-01W-0747-08) from TCGA case TCGA-17-Z052, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z052-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec4ae919-52e3-41d2-9d32-666464c26fb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z052-11A (Solid Tissue Normal), aliquot TCGA-17-Z052-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ead57400-bbc8-43f7-9738-96408fccbc36

The open-access MAF lists 119 somatic variants for this specimen: 97 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 19, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1, Splice Region 1, Intron 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; called by muse, mutect2, varscan2
- ATP12A | c.1681G>T p.G561C | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54512761; called by muse, mutect2
- CACNA1G | c.1032G>T p.W344C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100662483; called by muse, mutect2, varscan2
- DDX50 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65292352; called by muse, mutect2
- EFCAB7 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as COSV52132128; called by muse, mutect2
- FAF1 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1272784573; called by muse, mutect2
- FBXL7 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV100310443; called by muse, mutect2
- FCRL3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 25/182 reads (14%) | catalogued as COSV63840869; called by muse, mutect2, varscan2
- GALNT14 | c.687T>A p.D229E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204290; called by muse, mutect2
- GRAMD1A | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs777364613; called by muse, mutect2
- LAMB1 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55968842; called by muse, mutect2, varscan2
- MAGEC3 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs963081342; called by muse, mutect2
- MNDA | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933333; called by muse, mutect2, varscan2
- MYH1 | c.5035G>T p.E1679* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV56857946; called by muse, mutect2, varscan2
- MYO10 | c.4351G>T p.V1451F | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs142263783; called by muse, varscan2
- NRXN2 | c.1703A>T p.D568V | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99635237; called by muse, mutect2
- OR4L1 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99044176; called by muse, mutect2, varscan2
- OR4Q3 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV59177621, COSV59178508; called by muse, mutect2, varscan2
- OR5T3 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs755903046, COSV57380207; called by muse, mutect2
- PCDHA3 | c.1176C>G p.H392Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.125); catalogued as rs1270625936, COSV63545415; called by muse, mutect2
- PCDHB3 | c.1054G>C p.V352L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs895272963; called by muse, mutect2, varscan2
- PILRA | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99546567; called by muse, mutect2
- PKHD1 | c.5656A>G p.M1886V | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs1439487801; called by muse, mutect2
- PYHIN1 | c.911T>G p.I304S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100932347; called by muse, mutect2, varscan2
- QSOX2 | c.2048G>T p.R683L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62393570; called by muse, mutect2
- RCSD1 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV63257955; called by muse, mutect2
- SH2D4B | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs768694588, COSV57902910; called by muse, mutect2, varscan2
- SLC37A2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53524845; called by muse, mutect2
- TAB2 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as rs1226594569; called by muse, mutect2
- TG | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99598704; called by muse, mutect2
- TGFBI | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1215819431, COSV59351988; called by muse, mutect2
- TTI2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs965731804; called by muse, varscan2
- ZIC1 | c.750C>A p.H250Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV51556592, COSV51559469; called by muse, mutect2
- ZIC4 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV67173413; called by muse, mutect2
- ZNF502 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV56074104; called by muse, mutect2
- AADACL4 | c.875A>T p.K292M | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- ABCG8 | c.608C>A p.T203N | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRA3 | c.2482-2A>T p.X828_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- AL592490.1 | c.908G>T p.S303I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ALDH8A1 | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.7311A>C p.Q2437H | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- APCS | c.291C>G p.H97Q | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- ARHGEF12 | c.1880C>G p.P627R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); called by muse, mutect2
- ARID5B | c.2450G>T p.R817M | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- CALCB | c.321C>A p.N107K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CAMP | c.347C>A p.T116N (on ENST00000296435; = p.T113N on NM_004345.5) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.44); called by muse, mutect2
- CENPJ | c.2050G>C p.E684Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CFAP65 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); called by muse, mutect2
- CNKSR2 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 28/711 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- CNTN5 | c.2422G>T p.G808C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COMMD2 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.264); called by muse, mutect2
- COMMD2 | c.229-1G>T p.X77_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- CSMD2 | c.7891A>G p.T2631A | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.145); called by muse, mutect2
- DNAH5 | c.11920G>T p.D3974Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- EXPH5 | c.3974C>G p.T1325S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM216B | c.343A>G p.R115G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FBXO43 | c.167T>A p.I56N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- FLG2 | c.2599C>G p.Q867E | Missense Mutation (SNP) | VAF 12/369 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.407); called by muse, mutect2
- FRMPD4 | c.1759A>T p.M587L | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.16406T>C p.M5469T | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.027); called by muse, mutect2
- GALNT11 | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); called by muse, mutect2
- GJD2 | c.531C>A p.H177Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- IFNA10 | c.427G>C p.V143L | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); called by muse, mutect2
- IGLV2-8 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- INPP4B | c.1589del p.K530Rfs*3 | Frame Shift Del (DEL) | VAF 53/462 reads (11%) | called by mutect2, pindel, varscan2
- KCNN2 | c.997G>A p.E333K (on ENST00000264773; = p.E545K on NM_021614.4) | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- LEMD1 | c.76A>G p.I26V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MTRR | c.2164G>A p.D722N (on ENST00000264668; = p.D695N on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NALCN | c.3992G>A p.S1331N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEFL | c.1053C>G p.I351M | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2
- NEXMIF | c.3855G>T p.L1285F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2
- NHS | c.4717G>C p.A1573P | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- NMBR | c.820T>C p.C274R | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2
- OR2L3 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR2M2 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, varscan2
- OR2T4 | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.953); called by muse, mutect2
- OR4S1 | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- PAPPA2 | c.294C>A p.D98E | Missense Mutation (SNP) | VAF 59/622 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- PCDHA7 | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2
- PCDHB12 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDZRN4 | c.2794A>G p.M932V (on ENST00000402685 / NM_001164595.2; = p.M674V on NM_013377.4) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PGD | c.909G>C p.K303N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PRSS35 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- RBM3 | c.468C>A p.D156E | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, mutect2
- SAMHD1 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHQ1 | c.1669G>T p.G557C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- SLC1A2 | c.1194G>T p.M398I | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC45A2 | c.1576G>T p.V526F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- SLC45A2 | c.1368+8G>C | Splice Region (SNP) | VAF 16/450 reads (4%) | called by muse, mutect2
- SLC8A3 | c.1991C>G p.P664R (on ENST00000381269 / NM_183002.3; = p.P662R on NM_033262.4) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.698); called by muse, mutect2
- SMAD5 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2
- SYNE1 | c.6923A>G p.Q2308R (on ENST00000367255 / NM_182961.4; = p.Q2315R on NM_033071.3) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- TECTA | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2
- TRIM17 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- ZIC2 | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ZNF552 | c.997T>C p.F333L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF669 | c.1268G>T p.C423F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- BTK | c.786C>T p.G262= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- COL14A1 | c.1785T>A p.P595= | Silent (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- F8 | c.5907T>C p.N1969= | Silent (SNP) | VAF 11/189 reads (6%) | called by muse, mutect2
- IL1RAPL1 | c.933G>T p.G311= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV100144959, COSV56260915; called by muse, mutect2
- KCNJ3 | c.735C>A p.P245= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.40084T>C p.L13362= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- NFASC | c.1053C>T p.G351= (on ENST00000339876 / NM_001378329.1; = p.G362= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs759321099; called by mutect2, varscan2
- NPR1 | c.1942C>T p.L648= | Silent (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- NPY2R | c.810G>C p.L270= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1233326472; called by muse, mutect2
- NRXN2 | c.1701G>T p.L567= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- OR2G2 | c.774C>A p.I258= | Silent (SNP) | VAF 20/187 reads (11%) | catalogued as rs865888004; called by muse, mutect2, varscan2
- PAMR1 | c.2022G>T p.P674= (on ENST00000619888 / NM_001001991.3; = p.P691= on NM_015430.4) | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- PRSS35 | c.550C>T p.L184= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- RNF20 | c.1558C>T p.L520= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as rs191603421; called by muse, mutect2
- RP1L1 | c.6303A>G p.V2101= | Silent (SNP) | VAF 38/490 reads (8%) | catalogued as rs1369755362; called by muse, mutect2
- SMYD1 | c.1056G>T p.R352= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV101352407; called by muse, mutect2
- SPTA1 | c.6900G>A p.L2300= | Silent (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- TAC3 | c.27C>T p.A9= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- ZFC3H1 | c.453C>T p.Y151= | Silent (SNP) | VAF 67/192 reads (35%) | catalogued as COSV57349537; called by muse, mutect2, varscan2
- DENND10P1 | n.439T>G | RNA (SNP) | VAF 9/249 reads (4%) | called by muse, mutect2
- MAX | c.172-6240G>A | Intron (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2
- MYADM | chr19:53874150 G>T | 3'Flank (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
